TCGA case TCGA-D3-A1Q8 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7b7a49b5-5be8-4966-8f3a-e6e01e694f86

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 33 years; Vital status: Dead; Days to death: 854 days (2.3 years).

Diagnoses (10)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: Progression; Age at diagnosis: 33.8 years (12,330 days); Year of diagnosis: 2004; AJCC staging edition: 7th; AJCC pathologic T: T0; AJCC pathologic N: N3; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 80 days; Days to treatment end: 94 days; Treatment dose: 3,000 cGy; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Mediastinum, NOS. Age at diagnosis: 34.2 years (12,477 days); Days to diagnosis: 147 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 34.2 years (12,477 days); Days to diagnosis: 147 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 34.9 years (12,764 days); Days to diagnosis: 434 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues, NOS. Age at diagnosis: 35.3 years (12,877 days); Days to diagnosis: 547 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 575 days (1.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 35.5 years (12,974 days); Days to diagnosis: 644 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues, NOS. Age at diagnosis: 35.5 years (12,974 days); Days to diagnosis: 644 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 657 days (1.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
8. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Pancreas, NOS. Age at diagnosis: 35.9 years (13,107 days); Days to diagnosis: 777 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
9. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Gallbladder. Age at diagnosis: 35.9 years (13,107 days); Days to diagnosis: 777 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
10. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 35.9 years (13,109 days); Days to diagnosis: 779 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (10 entries)
- Day 147 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Mediastinum, NOS; Days to progression: 147 days.
- Day 147 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 147 days.
- Day 434 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 434 days (1.2 years).
- Day 547 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 547 days (1.5 years).
- Day 644 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 644 days (1.8 years).
- Day 644 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 644 days (1.8 years).
- Day 777 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pancreas, NOS; Days to progression: 777 days (2.1 years).
- Day 777 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Gallbladder; Days to progression: 777 days (2.1 years).
- Day 779 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 779 days (2.1 years).
- Days to follow up: 854 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 161 kg; Height: 187 cm; BMI: 46.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A1Q8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-D3-A1Q8-06A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A1Q8-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A1Q8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 854 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 854 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 147 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A1Q8-06A-11D-A192-01): tumor purity 0.53, ploidy 1.77, whole-genome doublings 0.
